Somatic mutation profile of tumor specimen TCGA-CV-6936-01A (aliquot TCGA-CV-6936-01A-11D-1912-08) from TCGA case TCGA-CV-6936, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 68.5 years (25,020 days).
Specimen TCGA-CV-6936-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4937f520-2dd9-4db7-a95a-7f35f9a0ca96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6936-10A (Blood Derived Normal), aliquot TCGA-CV-6936-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ec4357d-fd97-4f24-88af-c873d0681ec2

The open-access MAF lists 284 somatic variants for this specimen: 210 protein-altering or splice-affecting, 71 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 184, Silent 71, Nonsense Mutation 12, Splice Site 5, Frame Shift Del 5, RNA 2, Frame Shift Ins 2, Splice Region 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TBX6 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200175825, CM154544, COSV99661396; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 34/57 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.7396C>G p.L2466V | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV71293376; called by muse, mutect2
- ABCA8 | c.2812A>G p.R938G | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs1232500427, COSV52201514; called by muse, mutect2, varscan2
- ABCC5 | c.256A>G p.S86G | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99656192; called by muse, mutect2, varscan2
- ACSS3 | c.430T>A p.F144I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99698063; called by muse, mutect2, varscan2
- ADAMTS14 | c.1868C>T p.S623F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs370358418; called by muse, mutect2, varscan2
- ADCK2 | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99301314; called by muse, mutect2, varscan2
- ADGRA3 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.145); catalogued as rs770806145, COSV100529186, COSV100529645; called by muse, mutect2
- AGTR1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.058); catalogued as COSV100836893; called by muse, mutect2, varscan2
- AHCTF1 | c.2993A>G p.N998S (on ENST00000366508; = p.N972S on NM_015446.5) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs369798428; called by muse, mutect2, varscan2
- AHDC1 | c.2749G>A p.A917T | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs749511928, COSV99898734; called by muse, mutect2, varscan2
- AKT1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.76); PolyPhen benign (0.158); catalogued as COSV62573196; called by muse, mutect2, varscan2
- ANK3 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.984); catalogued as COSV99777628, COSV99778253; called by muse, mutect2, varscan2
- ANKFN1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.841); catalogued as rs554736337, COSV100592936; called by muse, mutect2, varscan2
- ANKRD34B | c.1127C>G p.S376* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100103335, COSV58614554; called by muse, mutect2
- ANO4 | c.2558T>C p.L853P (on ENST00000392977 / NM_001286615.2; = p.L818P on NM_178826.4) | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); catalogued as COSV100151324, COSV54609102; called by muse, mutect2
- APOB | c.13409C>T p.S4470F | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.785); catalogued as COSV51950788; called by muse, mutect2, varscan2
- ARHGAP27 | c.1649C>T p.S550F (on ENST00000428638 / NM_001282290.1; = p.S209F on NM_199282.3) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV100976432; called by muse, mutect2, varscan2
- ARHGAP35 | c.4287C>G p.I1429M | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101350593; called by muse, mutect2, varscan2
- ARR3 | c.8A>C p.K3T | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100330769; called by muse, mutect2, varscan2
- ASMTL | c.274-1G>A p.X92_splice | Splice Site (SNP) | VAF 11/91 reads (12%) | catalogued as COSV101187623; called by muse, mutect2, varscan2
- ATP2A2 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV100428297, COSV100428404; called by muse, mutect2, varscan2
- ATP6AP2 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as COSV101011417; called by muse, mutect2, varscan2
- BOC | c.1957A>T p.I653F | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV99847784; called by muse, mutect2, varscan2
- BOD1L1 | c.4711A>T p.N1571Y | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV99238056; called by muse, mutect2, varscan2
- BRCA2 | c.8707G>A p.E2903K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as CM1410473, COSV101203803; called by muse, mutect2
- CALML4 | c.446T>A p.L149Q | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100682783; called by muse, mutect2, varscan2
- CCDC181 | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV63157775, COSV63158268; called by muse, mutect2
- CCT3 | c.453G>C p.M151I | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99827015; called by muse, mutect2
- CDH9 | c.2210C>T p.T737M | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1346865409, COSV50303173, COSV50488057; called by muse, mutect2, varscan2
- CFH | c.2938C>T p.H980Y | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV66409630, COSV66413374; called by muse, mutect2
- CHD3 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); catalogued as COSV100390516; called by muse, mutect2, varscan2
- CHI3L2 | c.416G>C p.G139A | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63873812; called by muse, mutect2
- CHIC2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as rs771347608, COSV99815914; called by muse, mutect2, varscan2
- CHIT1 | c.1210C>T p.Q404* | Nonsense Mutation (SNP) | VAF 13/141 reads (9%) | catalogued as COSV99704949; called by muse, mutect2
- CLASRP | c.716T>A p.L239H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); catalogued as COSV99673385; called by muse, mutect2, varscan2
- CLTCL1 | c.2555G>C p.R852T | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV54225512, COSV99594323; called by muse, mutect2
- CNGB3 | c.1259T>C p.I420T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100180959; called by muse, mutect2, varscan2
- COL8A1 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53734840; called by muse, mutect2
- CPED1 | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.783); catalogued as COSV60012972; called by muse, mutect2, varscan2
- CRYBA4 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100697717; called by muse, varscan2
- CSMD1 | c.1646C>A p.T549K (on ENST00000520002; = p.T548K on NM_033225.6) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100141669; called by muse, varscan2
- CSMD3 | c.6148G>T p.D2050Y (on ENST00000297405 / NM_001363185.1; = p.D1946Y on NM_052900.3) | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV99820486; called by muse, mutect2, varscan2
- CSPP1 | c.949C>T p.R317C (on ENST00000676605; = p.R276C on NM_024790.6) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.111); catalogued as rs114953032, COSV51584805; called by mutect2, varscan2
- CTNNA2 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.057); catalogued as COSV100781212; called by muse, mutect2, varscan2
- CYP3A7 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV60481452; called by muse, mutect2, varscan2
- DACH1 | c.1729G>A p.E577K (on ENST00000619232 / NM_001366712.1; = p.E323K on NM_004392.6) | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.038); catalogued as rs1339631979, COSV100497246; called by muse, mutect2, varscan2
- DDN | c.407G>C p.R136P | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV100304799; called by muse, mutect2, varscan2
- DDX24 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs1311470963, COSV100427781; called by muse, mutect2, varscan2
- DGCR2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.009); catalogued as COSV99593129; called by muse, mutect2, varscan2
- DHX8 | c.2413C>T p.P805S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99291791; called by muse, mutect2, varscan2
- DLEC1 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.176); catalogued as rs760214352, COSV100341107; called by muse, mutect2, varscan2
- DNAH5 | c.1981C>T p.R661C | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs763771549, COSV54216174; called by muse, mutect2, varscan2
- DNAH7 | c.10220G>A p.R3407H | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs186433996; called by muse, mutect2, varscan2
- DNAH8 | c.5031C>G p.I1677M | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV100542621; called by muse, mutect2, varscan2
- DNMT3A | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as rs757211277, COSV53056452; called by muse, mutect2, varscan2
- DPP10 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV59664482; called by muse, mutect2
- DTNA | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as rs777787083, COSV99310219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EEA1 | c.1660C>G p.Q554E | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.93); catalogued as COSV100466824; called by muse, mutect2, varscan2
- EHBP1 | c.2932G>A p.E978K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.16); catalogued as COSV50442727, COSV99859661; called by muse, mutect2, varscan2
- ENTPD7 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100978324; called by muse, mutect2, varscan2
- ERC2 | c.2341C>T p.Q781* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99879544; called by muse, mutect2, varscan2
- ERCC4 | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1567243693, COSV100318558; ClinVar: uncertain significance; called by muse, mutect2
- EXD2 | c.757C>T p.L253F (on ENST00000312994 / NM_001193362.1; = p.L128F on NM_018199.3) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100473575, COSV100474444; called by muse, mutect2, varscan2
- FAT1 | c.872C>G p.S291C | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV101498591; called by muse, mutect2, varscan2
- FBXO42 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.188); catalogued as COSV100981587; called by muse, mutect2
- FKBPL | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV100913525; called by muse, mutect2, varscan2
- FLT4 | c.573G>T p.M191I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV99985598; called by muse, mutect2, varscan2
- FMOD | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 116/231 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367961930; called by muse, mutect2, varscan2
- FN1 | c.1474C>G p.H492D | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100115419; called by muse, mutect2, varscan2
- FOXRED2 | c.1901A>G p.H634R | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.028); catalogued as COSV99340618; called by muse, mutect2, varscan2
- FRK | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV101606615; called by muse, mutect2, varscan2
- FRY | c.8988C>A p.Y2996* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as COSV100968660; called by muse, mutect2, varscan2
- GABPA | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV61397277; called by muse, mutect2, varscan2
- GET1 | c.168G>A p.M56I | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as COSV100414320; called by mutect2, varscan2
- GLI1 | c.1522C>G p.Q508E | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.194); catalogued as COSV57357640, COSV99953533; called by muse, mutect2, varscan2
- GPR155 | c.167G>C p.G56A | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99789589; called by muse, mutect2, varscan2
- GRM2 | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.536); catalogued as COSV99622273; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.490G>A p.D164N (on ENST00000354667 / NM_031243.3; = p.D152N on NM_002137.4) | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100522837, COSV61160465; called by muse, mutect2, varscan2
- IFI27L1 | c.59G>C p.G20A | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.152); catalogued as COSV101267196; called by muse, mutect2, varscan2
- IFT80 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100424223; called by muse, mutect2, varscan2
- IKBKB | c.1824C>G p.I608M | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.155); catalogued as COSV100645541; called by muse, mutect2, varscan2
- IL6R | c.1369T>G p.Y457D | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV100690397; called by muse, mutect2
- ILF2 | c.690G>C p.L230F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV100721797; called by muse, varscan2
- ITGA11 | c.3257G>T p.G1086V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV100240657; called by muse, mutect2, varscan2
- KCNH5 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100524882; called by muse, mutect2, varscan2
- KDM5D | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 71/81 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58735971; called by muse, mutect2, varscan2
- KEL | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs199731371, COSV62333799; called by muse, mutect2
- KIAA0100 | c.1517G>C p.S506T | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV101197179; called by muse, mutect2, varscan2
- KIAA1755 | c.2398G>C p.D800H | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); catalogued as COSV99641287; called by muse, mutect2
- KIRREL2 | c.1775G>A p.G592E | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1466561010, COSV99383402; called by muse, mutect2, varscan2
- KLHL12 | c.1239G>C p.Q413H | Missense Mutation (SNP) | VAF 30/301 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as rs1557984633, COSV100935854; called by muse, mutect2, varscan2
- LAMC3 | c.4021G>C p.D1341H | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.615); catalogued as rs763226461, COSV100735860; called by muse, mutect2, varscan2
- LEPR | c.2729C>A p.P910H | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100847706; called by muse, mutect2, varscan2
- LIN9 | c.634G>C p.D212H (on ENST00000366808 / NM_001270410.2; = p.D157H on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100066881; called by muse, mutect2, varscan2
- LNPEP | c.902C>G p.S301C | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as rs1255978481, COSV99183459; called by muse, mutect2, varscan2
- LRGUK | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.025); catalogued as rs563421721, COSV99603599; called by muse, mutect2, varscan2
- LRP1B | c.8572C>G p.L2858V | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.166); catalogued as COSV101249661; called by muse, mutect2, varscan2
- LRRC4C | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV53434224; called by muse, mutect2, varscan2
- LRRN1 | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 19/28 reads (68%) | catalogued as COSV100075932; called by muse, mutect2, varscan2
- MACF1 | c.859A>G p.I287V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as COSV100481697; called by muse, mutect2, varscan2
- MBTPS1 | c.1544A>T p.N515I | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100597246; called by muse, mutect2, varscan2
- MDGA2 | c.1606G>C p.V536L (on ENST00000399232 / NM_001113498.2; = p.V238L on NM_182830.4) | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV100636063; called by muse, mutect2, varscan2
- MID1IP1 | c.481C>G p.L161V | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100423619; called by muse, varscan2
- MOS | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.985); catalogued as COSV100322663, COSV100322940; called by muse, mutect2, varscan2
- MRTFA | c.561C>A p.N187K | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100843774; called by muse, mutect2, varscan2
- MUC17 | c.1933G>C p.E645Q | Missense Mutation (SNP) | VAF 124/618 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as COSV100071059, COSV60287714; called by muse, mutect2, varscan2
- MUC17 | c.4335A>G p.I1445M | Missense Mutation (SNP) | VAF 232/500 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779048358, COSV60302950; called by muse, varscan2
- MUC5AC | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); catalogued as rs573714547, COSV100650485; called by muse, mutect2, varscan2
- MYBL1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs780243831, COSV101576445; called by muse, mutect2, varscan2
- MYH7 | c.5461G>C p.E1821Q | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100805548; called by muse, mutect2, varscan2
- MYH8 | c.2400G>C p.M800I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101238044; called by muse, mutect2, varscan2
- MYO5A | c.3278A>T p.D1093V | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV100697162; called by muse, mutect2, varscan2
- NALCN | c.1411C>T p.H471Y | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.303); catalogued as COSV99212642; called by muse, mutect2, varscan2
- NBEAL2 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.225); catalogued as rs748294958, COSV99433923; called by muse, varscan2
- NIPBL | c.5510G>A p.R1837Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV99238191; called by muse, mutect2
- NOL4 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774633323, COSV52344423, COSV52349065; called by muse, mutect2, varscan2
- NRG2 | c.1582A>T p.S528C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99179851; called by muse, mutect2, varscan2
- NRM | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.206); catalogued as COSV99223456; called by muse, mutect2, varscan2
- NRXN2 | c.2170C>T p.R724W | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs765856391, COSV99631981; called by muse, mutect2, varscan2
- NUP62 | c.155C>G p.T52R | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV100351701; called by muse, mutect2
- OR2L3 | c.513G>T p.R171S | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV63455292; called by muse, varscan2
- OR5AR1 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 13/215 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV100265516; called by muse, mutect2
- OSGIN2 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.547); catalogued as rs1323848797, COSV99857987; called by muse, mutect2
- PABPC4 | c.1775G>A p.G592E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100865399; called by muse, mutect2, varscan2
- PADI2 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.441); catalogued as rs752923211, COSV100971743; called by muse, mutect2, varscan2
- PADI4 | c.408+1G>A p.X136_splice | Splice Site (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100966648; called by muse, mutect2
- PAIP1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV100166442; called by muse, mutect2, varscan2
- PARP12 | c.1591C>T p.R531* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as rs1423887281, COSV54934698; called by mutect2, varscan2
- PAWR | c.833A>T p.E278V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100174013; called by muse, mutect2, varscan2
- PCDHA5 | c.2197C>T p.R733W | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.145); catalogued as rs140039635; called by muse, mutect2, varscan2
- PCLO | c.13808A>T p.E4603V | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV100426123; called by muse, mutect2, varscan2
- PDE10A | c.1888A>T p.I630F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV100604116; called by muse, mutect2, varscan2
- PDS5A | c.3595G>C p.E1199Q | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.609); catalogued as COSV100337051; called by muse, mutect2
- PFN4 | c.71T>A p.I24N | Missense Mutation (SNP) | VAF 72/128 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100500340; called by muse, mutect2, varscan2
- PHPT1 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 50/73 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56034027; called by muse, mutect2, varscan2
- PHRF1 | c.302C>G p.S101C | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99199340; called by muse, mutect2, varscan2
- PI4KA | c.1579C>T p.Q527* | Nonsense Mutation (SNP) | VAF 14/183 reads (8%) | catalogued as COSV99743669; called by muse, mutect2
- PIK3C2B | c.4180G>C p.E1394Q | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV65812822; called by muse, mutect2
- PLCE1 | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as COSV99592923; called by muse, mutect2
- PLCG1 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV99718342; called by muse, mutect2, varscan2
- PLEC | c.8005G>C p.E2669Q (on ENST00000322810 / NM_201380.4; = p.E2559Q on NM_000445.5) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as rs1554688949, COSV100509081, COSV100509276; called by muse, mutect2
- PNLIPRP2 | c.866A>T p.Y289F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100077496; called by muse, mutect2, varscan2
- POLR2A | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV100495415; called by muse, mutect2, varscan2
- PPP1R12B | c.1889C>G p.S630C | Missense Mutation (SNP) | VAF 45/73 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99294452; called by muse, mutect2, varscan2
- PRDM14 | c.1574C>G p.S525C | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV52574594; called by muse, mutect2, varscan2
- PREP | c.459G>T p.Q153H (on ENST00000369110; = p.Q219H on NM_002726.5) | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100963629; called by muse, mutect2, varscan2
- PRLR | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as COSV99184175; called by muse, mutect2, varscan2
- PSG5 | c.372C>G p.I124M | Missense Mutation (SNP) | VAF 117/367 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as COSV100742515; called by muse, mutect2, varscan2
- PSIP1 | c.1105-2A>G p.X369_splice | Splice Site (SNP) | VAF 11/30 reads (37%) | catalogued as COSV101050856; called by muse, mutect2, varscan2
- QRFPR | c.1269G>T p.E423D | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.01); catalogued as COSV57675160; called by muse, mutect2, varscan2
- RBM5 | c.1723G>C p.E575Q | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV61739335; called by muse, mutect2, varscan2
- REG1B | c.98G>C p.R33P | Missense Mutation (SNP) | VAF 75/134 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV100521220, COSV59308357; called by muse, mutect2, varscan2
- REN | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as COSV99689341; called by muse, mutect2, varscan2
- RHPN1 | c.2009C>T p.P670L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1364300425, COSV100000322, COSV56649018; called by muse, mutect2, varscan2
- RNF208 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT tolerated (0.85); PolyPhen benign (0.088); catalogued as COSV100763091; called by muse, mutect2, varscan2
- RPA1 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs1027723036, COSV99627564; called by muse, mutect2, varscan2
- SAMD10 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1368089363, COSV53870178; called by muse, mutect2
- SEL1L | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.98); catalogued as COSV100377571; called by muse, mutect2
- SENP6 | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100518876; called by muse, mutect2, varscan2
- SFMBT1 | c.1538C>G p.S513* | Nonsense Mutation (SNP) | VAF 14/26 reads (54%) | catalogued as COSV56257346, COSV99965715; called by muse, mutect2, varscan2
- SHD | c.300G>A p.L100= | Splice Region (SNP) | VAF 34/94 reads (36%) | catalogued as COSV101619022; called by muse, mutect2, varscan2
- SIGLEC5 | c.1634C>T p.S545L | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs1276346326, COSV99706905; called by muse, mutect2, varscan2
- SLC24A4 | c.1864G>A p.D622N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); catalogued as rs1399933125, COSV100103901, COSV54114812; called by muse, mutect2
- SLC35G2 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 37/216 reads (17%) | catalogued as rs962937778, COSV67588092; called by muse, mutect2, varscan2
- SLC36A4 | c.56-2A>T p.X19_splice | Splice Site (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100419224; called by muse, mutect2, varscan2
- SLC39A4 | c.518C>A p.A173E (on ENST00000301305 / NM_001374839.1; = p.A148E on NM_017767.3) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.111); catalogued as COSV52778563; called by muse, mutect2, varscan2
- SLC41A1 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.68); catalogued as rs957512780, COSV65650677, COSV65651367; called by muse, mutect2
- SLC4A8 | c.763+2T>C p.X255_splice | Splice Site (SNP) | VAF 18/51 reads (35%) | catalogued as COSV100176297; called by muse, mutect2, varscan2
- SNX25 | c.790C>A p.P264T | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.476); catalogued as COSV99252172; called by muse, mutect2, varscan2
- SPARC | c.123A>G p.V41= | Splice Region (SNP) | VAF 36/113 reads (32%) | catalogued as COSV99163702; called by muse, mutect2, varscan2
- SPATA31E1 | c.3454A>G p.T1152A | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.043); catalogued as COSV100349695; called by muse, mutect2, varscan2
- SPTA1 | c.1476G>C p.M492I | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.45); catalogued as rs763410384, COSV100934006, COSV100934652; called by muse, mutect2, varscan2
- SSR1 | c.387C>A p.D129E | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV99783551; called by muse, mutect2, varscan2
- STAT1 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.139); catalogued as COSV100699941; called by muse, mutect2
- SVEP1 | c.8398G>C p.E2800Q | Missense Mutation (SNP) | VAF 82/138 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99927980; called by muse, mutect2, varscan2
- SYNE1 | c.5762C>T p.S1921F (on ENST00000367255 / NM_182961.4; = p.S1928F on NM_033071.3) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV99549539; called by muse, mutect2, varscan2
- SYT1 | c.569A>T p.K190M | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as COSV54059133, COSV99693082; called by muse, mutect2, varscan2
- TAB2 | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV99644397; called by muse, mutect2, varscan2
- TBC1D4 | c.3029G>T p.G1010V | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100884435, COSV66492812; called by muse, mutect2, varscan2
- TCN2 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99308321; called by muse, mutect2, varscan2
- TDRD3 | c.535T>G p.S179A | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99539554; called by muse, mutect2, varscan2
- TGM6 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as COSV99171649; called by mutect2, varscan2
- TMCO4 | c.37C>G p.Q13E | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV53872305, COSV99615488, COSV99616333; called by muse, mutect2
- TMPRSS11F | c.1046G>C p.R349T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.994); catalogued as rs1312354240, COSV62466569; called by muse, mutect2, varscan2
- TPR | c.3643G>A p.E1215K | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV100823516; called by muse, mutect2, varscan2
- TTC21A | c.573G>A p.M191I | Missense Mutation (SNP) | VAF 67/127 reads (53%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.968); catalogued as COSV100086747; called by muse, mutect2, varscan2
- TTN | c.18506A>C p.K6169T (on ENST00000591111; = p.K5242T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | PolyPhen benign (0.215); catalogued as COSV100588729; called by muse, mutect2, varscan2
- TTN | c.1867C>A p.Q623K (on ENST00000591111; = p.Q577K on NM_003319.4) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | PolyPhen benign (0.003); catalogued as COSV100588730; called by muse, mutect2, varscan2
- TTN | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 15/56 reads (27%) | PolyPhen benign (0.028); catalogued as rs761344572, COSV60049091; called by muse, mutect2, varscan2
- TUBGCP3 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99996430; called by muse, mutect2, varscan2
- UBQLN2 | c.917A>T p.Q306L | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100592594; called by muse, mutect2, varscan2
- YARS2 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100256263; called by muse, mutect2, varscan2
- ZIC4 | c.88C>A p.H30N | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV101267770; called by muse, mutect2, varscan2
- ZIC4 | c.87C>A p.H29Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.058); catalogued as COSV101267771; called by muse, mutect2, varscan2
- ZNF233 | c.698C>A p.A233D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as COSV100492042; called by muse, mutect2, varscan2
- ZNF266 | c.1067A>C p.D356A | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV100749297; called by muse, mutect2, varscan2
- ZNF638 | c.4624G>T p.V1542F | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747750667, COSV100037722; called by muse, mutect2, varscan2
- ZNF708 | c.174A>T p.Q58H | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100803017; called by muse, mutect2, varscan2
- ZNF91 | c.2941C>T p.L981F | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as rs1245011325, COSV100321853, COSV100323382; called by muse, mutect2
- ACIN1 | c.3892del p.D1298Tfs*119 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- FAT1 | c.2596del p.D866Tfs*8 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | called by mutect2, pindel, varscan2
- MS4A6E | c.429_435del p.W143* | Frame Shift Del (DEL) | VAF 32/124 reads (26%) | called by mutect2, pindel, varscan2
- NELL1 | c.2074dup p.S692Kfs*21 | Frame Shift Ins (INS) | VAF 53/163 reads (33%) | called by mutect2, pindel, varscan2
- NSUN4 | c.809del p.N270Tfs*72 | Frame Shift Del (DEL) | VAF 38/125 reads (30%) | called by mutect2, pindel, varscan2
- POLR2B | c.3364del p.C1122Vfs*3 | Frame Shift Del (DEL) | VAF 14/67 reads (21%) | called by mutect2, pindel, varscan2
- SRSF10 | c.487G>C p.D163H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- TFG | c.803dup p.Y268* | Nonsense Mutation (INS) | VAF 56/160 reads (35%) | called by pindel, varscan2
- TTN | c.38922dup p.V12975Sfs*5 (on ENST00000591111; = p.V5551Sfs*5 on NM_003319.4) | Frame Shift Ins (INS) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- ADAM29 | c.459C>T p.D153= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as rs1343920472, COSV100821855; called by muse, mutect2, varscan2
- ADAMTS5 | c.474C>T p.V158= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99536843; called by muse, mutect2, varscan2
- ALDH4A1 | c.966C>T p.F322= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs150927009, COSV51893029; called by muse, mutect2, varscan2
- ANKRD37 | c.93G>A p.K31= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as rs1274330309, COSV99248763; called by muse, mutect2, varscan2
- ASPRV1 | c.787C>T p.L263= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as COSV100208340; called by muse, mutect2, varscan2
- ATG2B | c.5691A>G p.L1897= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV55892198; called by muse, mutect2, varscan2
- BYSL | c.1227C>T p.P409= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as rs896266183, COSV100026640; called by muse, mutect2, varscan2
- CD320 | c.507C>T p.T169= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs1489014958, COSV100035722, COSV100035795; called by muse, mutect2, varscan2
- CDH19 | c.1473C>T p.I491= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV100050595; called by muse, mutect2, varscan2
- CFHR2 | c.372G>A p.E124= | Silent (SNP) | VAF 15/146 reads (10%) | catalogued as COSV66381586; called by muse, mutect2
- CHRDL1 | c.1185G>A p.E395= (on ENST00000372045; = p.E401= on NM_145234.4) | Silent (SNP) | VAF 49/66 reads (74%) | catalogued as COSV99487567; called by muse, mutect2, varscan2
- CLTCL1 | c.4128C>T p.L1376= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as rs1555935532, COSV99594321; called by muse, mutect2, varscan2
- CNGB3 | c.321G>A p.G107= | Silent (SNP) | VAF 70/321 reads (22%) | catalogued as COSV100180960; called by muse, mutect2, varscan2
- CNKSR2 | c.1053C>T p.L351= | Silent (SNP) | VAF 17/165 reads (10%) | catalogued as COSV99666987; called by muse, mutect2, varscan2
- CYP21A2 | c.912C>T p.A304= | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as rs751072381, COSV100925668; called by mutect2, varscan2
- DCAF4L1 | c.306C>T p.I102= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100295474; called by muse, mutect2, varscan2
- DIAPH3 | c.1980T>A p.T660= (on ENST00000400324 / NM_001042517.2; = p.T397= on NM_030932.3) | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs1425291008, COSV99932552; called by muse, mutect2, varscan2
- FLG2 | c.2781T>C p.S927= | Silent (SNP) | VAF 529/863 reads (61%) | catalogued as COSV101165531; called by muse, mutect2, varscan2
- GBX2 | c.600G>T p.S200= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as COSV60445408; called by muse, mutect2, varscan2
- GJB2 | c.336G>A p.K112= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs1566528568, CM125177, COSV101241460; called by muse, mutect2, varscan2
- GOLGB1 | c.4419A>G p.E1473= | Silent (SNP) | VAF 44/276 reads (16%) | catalogued as COSV100510163; called by muse, mutect2, varscan2
- GPC4 | c.12C>T p.F4= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs1240078663, COSV100895329; called by muse, mutect2, varscan2
- GRM1 | c.2583C>T p.G861= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs148042148; called by muse, mutect2, varscan2
- HACL1 | c.1230G>A p.Q410= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV100337102; called by muse, mutect2
- HK3 | c.2463C>T p.D821= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs200491262, COSV99457540; called by mutect2, varscan2
- HPGD | c.528G>A p.V176= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV56662119; called by muse, mutect2, varscan2
- KDM6B | c.2412C>G p.L804= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV54678281, COSV54683781; called by muse, mutect2, varscan2
- KIF13B | c.3750C>T p.I1250= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as rs375598915; called by muse, mutect2, varscan2
- KRT27 | c.273C>G p.L91= | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as COSV100053131; called by muse, mutect2, varscan2
- LYZL1 | c.471C>T p.I157= (on ENST00000375500; = p.I111= on NM_032517.6) | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100973578; called by muse, mutect2, varscan2
- MACO1 | c.1308G>A p.Q436= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV100974943; called by muse, mutect2, varscan2
- MAST1 | c.1122C>T p.F374= | Silent (SNP) | VAF 23/164 reads (14%) | catalogued as rs1475923113, COSV99262024; called by muse, mutect2, varscan2
- MBD5 | c.2331C>T p.N777= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV101289875; called by muse, mutect2, varscan2
- MEIS1 | c.942C>T p.L314= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs1432324216, COSV99714214; called by muse, mutect2, varscan2
- MLH1 | c.447G>A p.Q149= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as rs63750638, CM078824, COSV99212290; ClinVar: likely benign; called by muse, mutect2, varscan2
- MOS | c.894C>T p.S298= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100322665; called by muse, mutect2, varscan2
- MYBPC1 | c.642G>A p.L214= (on ENST00000550270 / NM_206820.2; = p.L239= on NM_002465.4) | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100637670; called by muse, mutect2, varscan2
- MYO18B | c.5709G>C p.L1903= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100122228; called by muse, mutect2
- NCOA6 | c.4407A>G p.K1469= | Silent (SNP) | VAF 34/189 reads (18%) | catalogued as COSV100749867; called by muse, mutect2, varscan2
- NEURL4 | c.738G>A p.V246= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs1428893773, COSV100223711; called by muse, mutect2, varscan2
- OBSCN | c.3465C>T p.F1155= | Silent (SNP) | VAF 12/236 reads (5%) | catalogued as COSV99470764; called by muse, mutect2
- OBSCN | c.19848A>G p.P6616= | Silent (SNP) | VAF 172/275 reads (63%) | catalogued as rs1332661655, COSV100800099; called by muse, mutect2, varscan2
- OR10C1 | c.105C>T p.I35= (on ENST00000622521; = p.I33= on NM_013941.3) | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV101010776; called by muse, mutect2, varscan2
- OR4Q3 | c.843C>A p.S281= | Silent (SNP) | VAF 22/188 reads (12%) | catalogued as COSV100056623, COSV59178383; called by muse, mutect2, varscan2
- PCDHB1 | c.2076C>A p.V692= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as COSV100127986; called by muse, mutect2, varscan2
- PCDHGA5 | c.2283G>A p.A761= | Silent (SNP) | VAF 13/166 reads (8%) | catalogued as rs555802357, COSV53920567, COSV53921770; called by muse, mutect2
- PCDHGB6 | c.1680G>A p.P560= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV53957598; called by muse, mutect2, varscan2
- PLP1 | c.324C>T p.I108= | Silent (SNP) | VAF 13/133 reads (10%) | catalogued as COSV100393222; called by muse, mutect2
- PMS1 | c.1578T>C p.C526= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100575382; called by muse, mutect2, varscan2
- PRORP | c.780A>C p.V260= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99154725; called by muse, mutect2, varscan2
- PRPSAP2 | c.201G>T p.V67= | Silent (SNP) | VAF 43/227 reads (19%) | catalogued as COSV99264257; called by muse, mutect2, varscan2
- RIOX1 | c.1353G>C p.R451= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV100407856; called by muse, mutect2, varscan2
- SERPINA7 | c.576C>T p.L192= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as COSV100568162, COSV59666978; called by muse, mutect2, varscan2
- SFRP4 | c.60C>T p.R20= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV99554151; called by muse, mutect2, varscan2
- SHISA3 | c.459C>G p.T153= | Silent (SNP) | VAF 32/148 reads (22%) | catalogued as COSV100069736; called by muse, mutect2, varscan2
- SLC19A1 | c.268C>T p.L90= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV100229037; called by muse, mutect2, varscan2
- SNX18 | c.714C>T p.S238= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs757806316, COSV100410107; called by muse, mutect2, varscan2
- SP140 | c.756C>T p.N252= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as rs754386576, COSV100613218; called by muse, mutect2, varscan2
- STKLD1 | c.312C>G p.L104= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100911840, COSV64311686; called by muse, mutect2, varscan2
- SYMPK | c.2472G>C p.L824= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV55611529, COSV99841263; called by muse, mutect2
- TBX1 | c.1050G>A p.T350= | Silent (SNP) | VAF 24/176 reads (14%) | catalogued as rs1033285427, COSV61547541; called by muse, mutect2, varscan2
- TCEAL4 | c.414C>T p.L138= | Silent (SNP) | VAF 13/154 reads (8%) | catalogued as COSV101010212; called by muse, mutect2
- TDRD5 | c.285G>A p.R95= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV99675132; called by muse, mutect2, varscan2
- TGFBR2 | c.1023C>T p.V341= | Silent (SNP) | VAF 57/99 reads (58%) | catalogued as COSV99846304; called by muse, mutect2, varscan2
- TTC37 | c.3057C>T p.Y1019= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs201249919, COSV100706245; called by muse, mutect2, varscan2
- TTN | c.38925G>A p.V12975= (on ENST00000591111; = p.V5551= on NM_003319.4) | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV59976990; called by mutect2, varscan2
- UBA1 | c.3126C>T p.D1042= | Silent (SNP) | VAF 26/43 reads (60%) | catalogued as rs782171722, COSV100255300; called by muse, mutect2, varscan2
- XIRP2 | c.3834T>G p.T1278= (on ENST00000628543; = p.T1453= on NM_152381.6) | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99736788; called by muse, mutect2, varscan2
- ZC3H18 | c.804C>T p.L268= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as rs772330430, COSV56328016; called by mutect2, varscan2
- ZFAT | c.2394G>A p.L798= | Silent (SNP) | VAF 29/148 reads (20%) | catalogued as COSV100914083; called by muse, mutect2, varscan2
- ZFHX4 | c.9744T>C p.N3248= | Silent (SNP) | VAF 40/185 reads (22%) | catalogued as COSV99254323; called by muse, mutect2, varscan2
- AC092718.3 | c.*60T>C | 3'UTR (SNP) | VAF 19/60 reads (32%) | catalogued as COSV101062725; called by muse, mutect2, varscan2
- IGKV1-13 | n.308G>A | RNA (SNP) | VAF 24/300 reads (8%) | catalogued as rs775652189; called by muse, mutect2
- SNORD116-24 | n.42G>A | RNA (SNP) | VAF 19/117 reads (16%) | catalogued as rs1184167118; called by muse, mutect2, varscan2
